Somatic mutation profile of tumor specimen C3N-00315-03 (aliquot CPT0012180009) from CPTAC case C3N-00315, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 69.0 years (25,193 days).
Specimen C3N-00315-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 612de3c6-8375-490d-9b7c-a27adb2088de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00315-31 (Blood Derived Normal), aliquot CPT0012240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ba9db83-0f65-423e-b303-4bd3157f68a1

The open-access MAF lists 121 somatic variants for this specimen: 92 protein-altering or splice-affecting, 20 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 20, Frame Shift Del 13, Nonsense Mutation 10, Intron 5, Splice Site 4, 5'Flank 2, Frame Shift Ins 2, 3'Flank 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF16 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as rs1031473979; called by muse, mutect2, varscan2
- CHD4 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.013); catalogued as COSV58911652; called by muse, varscan2
- CNOT6L | c.455G>A p.R152Q (on ENST00000504123 / NM_001286790.2; = p.R147Q on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs781330689, COSV53699998; called by muse, mutect2, varscan2
- DCAKD | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766601603; called by muse, mutect2, varscan2
- EDN3 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 141/552 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs748374290, COSV61108533; called by muse, mutect2, varscan2
- FBN2 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs766945762, COSV52503308; called by muse, mutect2
- GP5 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV59879373; called by muse, mutect2, varscan2
- LDLRAP1 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 76/271 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768454420, COSV65474119; called by muse, mutect2, varscan2
- LIX1L | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs1165313520, COSV60160788; called by muse, mutect2, varscan2
- LRIT2 | c.1327G>A p.G443S | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV100259296; called by mutect2, varscan2
- MFGE8 | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99183953; called by muse, mutect2, varscan2
- OR56A4 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV58110257; called by muse, mutect2, varscan2
- PRDX3 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1449856338; called by muse, varscan2
- RAD54L | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 25/402 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774775735, COSV64336258; called by muse, mutect2
- RPRD2 | c.3667C>G p.H1223D | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV64820450; called by muse, mutect2, varscan2
- SETD5 | c.4276C>T p.R1426* | Nonsense Mutation (SNP) | VAF 20/125 reads (16%) | catalogued as rs753779109; called by muse, mutect2
- SETX | c.7247A>G p.K2416R | Missense Mutation (SNP) | VAF 57/365 reads (16%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.736); catalogued as rs774026481; called by muse, mutect2, varscan2
- SETX | c.7246A>T p.K2416* | Nonsense Mutation (SNP) | VAF 55/367 reads (15%) | catalogued as COSV56380275; called by muse, mutect2, varscan2
- SLITRK1 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 41/318 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs866484290; called by muse, mutect2, varscan2
- SOX14 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100048321; called by muse, mutect2
- TRMT6 | c.1112+5G>T | Splice Region (SNP) | VAF 21/90 reads (23%) | catalogued as COSV52543218; called by muse, mutect2, varscan2
- UBR4 | c.3196G>C p.E1066Q | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.094); catalogued as COSV100920665; called by muse, mutect2
- UGT2B4 | c.384G>C p.K128N | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs768591561; called by muse, mutect2, varscan2
- VHL | c.482G>C p.R161P | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM951290, CM961431, COSV104374399, COSV56542648, COSV56545213, COSV56545244; called by muse, mutect2, varscan2
- ZNF208 | c.83T>C p.L28S | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV68103041; called by muse, mutect2, varscan2
- ADA2 | c.966del p.F322Lfs*20 (on ENST00000262607; = p.F81Lfs*20 on NM_177405.3) | Frame Shift Del (DEL) | VAF 11/109 reads (10%) | called by mutect2, pindel, varscan2
- ADAMTS1 | c.2564T>A p.F855Y | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ADGRA3 | c.1941dup p.P648Sfs*11 | Frame Shift Ins (INS) | VAF 28/242 reads (12%) | called by mutect2, pindel, varscan2
- ALS2 | c.334G>C p.A112P | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2
- ANKRD11 | c.2119del p.E707Kfs*12 | Frame Shift Del (DEL) | VAF 43/251 reads (17%) | called by mutect2, pindel, varscan2
- ATXN7 | c.2154del p.S719Pfs*32 | Frame Shift Del (DEL) | VAF 18/135 reads (13%) | called by mutect2, pindel, varscan2
- BRINP1 | c.2005_2017del p.L669Cfs*20 | Frame Shift Del (DEL) | VAF 18/192 reads (9%) | called by mutect2, pindel
- CADPS2 | c.2948A>T p.N983I | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.157); called by muse, mutect2
- CEP250 | c.1770A>T p.E590D | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- CEP57L1 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHD6 | c.4768A>T p.K1590* | Nonsense Mutation (SNP) | VAF 40/135 reads (30%) | called by muse, mutect2, varscan2
- CLDN10 | c.339A>T p.K113N | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.889); called by muse, mutect2
- DCAF1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- DNAH3 | c.10834C>A p.L3612I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- EPG5 | c.5776G>T p.D1926Y | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- EZH1 | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRK2 | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HBM | c.131del p.P44Rfs*3 | Frame Shift Del (DEL) | VAF 26/191 reads (14%) | called by mutect2, pindel, varscan2
- HIF1A | c.126del p.Q43Sfs*8 | Frame Shift Del (DEL) | VAF 22/166 reads (13%) | called by mutect2, pindel, varscan2
- HOXD10 | c.664A>T p.K222* | Nonsense Mutation (SNP) | VAF 82/567 reads (14%) | called by muse, mutect2, varscan2
- HRNR | c.8503A>C p.T2835P | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- KIAA1210 | c.2750C>G p.P917R | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- LIF | c.333C>G p.Y111* | Nonsense Mutation (SNP) | VAF 53/375 reads (14%) | called by muse, mutect2, varscan2
- LRRK2 | c.4933T>C p.Y1645H | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LYN | c.275T>G p.V92G | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MAEL | c.17C>G p.A6G | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- MALRD1 | c.2992-1G>T p.X998_splice | Splice Site (SNP) | VAF 22/146 reads (15%) | called by muse, mutect2, varscan2
- MANBA | c.1805G>T p.G602V (on ENST00000642252; = p.G556V on NM_005908.4) | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MANBA | c.1804G>A p.G602R (on ENST00000642252; = p.G556R on NM_005908.4) | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MANBA | c.1803T>G p.Y601* (on ENST00000642252; = p.Y555* on NM_005908.4) | Nonsense Mutation (SNP) | VAF 28/270 reads (10%) | called by muse, varscan2
- MFF | c.656del p.A219Vfs*59 | Frame Shift Del (DEL) | VAF 19/140 reads (14%) | called by mutect2, pindel, varscan2
- MTDH | c.682A>G p.I228V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYT1L | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 34/214 reads (16%) | called by muse, mutect2, varscan2
- NEDD4 | c.2979G>T p.W993C (on ENST00000508342 / NM_001284338.1; = p.W574C on NM_006154.4) | Missense Mutation (SNP) | VAF 51/348 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NMD3 | c.485_486+4del p.X162_splice | Splice Site (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel
- NUP98 | c.3490C>A p.H1164N (on ENST00000359171 / NM_001365126.1; = p.H1147N on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NWD2 | c.3639G>T p.E1213D | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.97); called by muse, varscan2
- NWD2 | c.3640C>T p.L1214F | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, varscan2
- NWD2 | c.3641T>A p.L1214H | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, varscan2
- OR2B2 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ORM2 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 69/576 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PCDHGC4 | c.1030A>T p.N344Y | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNX4 | c.162G>C p.W54C | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- PCYOX1 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PIEZO1 | c.2092C>A p.L698M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PLA2G4E | c.2143C>G p.P715A | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); called by muse, mutect2
- PLET1 | c.557T>G p.F186C | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PLXNB2 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PODN | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 40/153 reads (26%) | called by muse, mutect2, varscan2
- PRRC2A | c.6175C>T p.Q2059* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- PTCD3 | c.1889T>C p.V630A | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- RPRD2 | c.3668A>T p.H1223L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- SDC1 | c.60_66+15del p.X20_splice | Splice Site (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel
- SLC14A2 | c.587del p.F196Sfs*5 | Frame Shift Del (DEL) | VAF 16/186 reads (9%) | called by mutect2, pindel
- SLC22A4 | c.1376T>G p.M459R | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- STARD7 | c.89T>A p.V30D | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SUPV3L1 | c.1204+2T>C p.X402_splice | Splice Site (SNP) | VAF 34/192 reads (18%) | called by muse, mutect2, varscan2
- SYNE1 | c.25913_25929del p.I8638Tfs*22 (on ENST00000367255 / NM_182961.4; = p.I8590Tfs*22 on NM_033071.3) | Frame Shift Del (DEL) | VAF 29/303 reads (10%) | called by mutect2, pindel
- SYNE2 | c.20089del p.R6697Gfs*4 | Frame Shift Del (DEL) | VAF 30/224 reads (13%) | called by mutect2, pindel, varscan2
- TBC1D10A | c.403C>G p.P135A | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TBX2 | c.404del p.F135Sfs*20 | Frame Shift Del (DEL) | VAF 21/100 reads (21%) | called by mutect2, pindel
- TCOF1 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2
- TTN | c.34021_34023delinsTG p.R11341Wfs*8 (on ENST00000591111; = p.R10414Wfs*8 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/209 reads (11%) | called by pindel, varscan2*
- WAPL | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFHX3 | c.882_883dup p.R295Pfs*5 | Frame Shift Ins (INS) | VAF 24/150 reads (16%) | called by mutect2, pindel, varscan2
- ZNF502 | c.1131del p.K377Nfs*78 | Frame Shift Del (DEL) | VAF 22/109 reads (20%) | called by mutect2, pindel, varscan2
- ZNF780B | c.1374C>G p.Y458* | Nonsense Mutation (SNP) | VAF 27/230 reads (12%) | called by muse, mutect2, varscan2
- ALS2 | c.3468A>T p.V1156= | Silent (SNP) | VAF 39/237 reads (16%) | called by muse, mutect2, varscan2
- BBS9 | c.60T>C p.F20= | Silent (SNP) | VAF 25/270 reads (9%) | called by muse, mutect2
- CNOT11 | c.435C>T p.F145= | Silent (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- CPN1 | c.396C>T p.D132= | Silent (SNP) | VAF 22/322 reads (7%) | catalogued as rs1287062961, COSV100962765; called by muse, mutect2
- ETV6 | c.1113G>T p.V371= | Silent (SNP) | VAF 18/173 reads (10%) | called by muse, varscan2
- F10 | c.516T>C p.C172= | Silent (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- FCGBP | c.2421G>A p.Q807= | Silent (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- KIAA1210 | c.2751C>G p.P917= | Silent (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- KIAA1755 | c.3333G>A p.G1111= | Silent (SNP) | VAF 17/192 reads (9%) | called by muse, mutect2
- KRT33B | c.1167T>G p.P389= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- NEK1 | c.3729T>C p.L1243= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- NLRP12 | c.828C>T p.S276= | Silent (SNP) | VAF 31/238 reads (13%) | catalogued as rs1467922706, COSV60753804; called by muse, mutect2, varscan2
- PKD1L1 | c.6033C>G p.S2011= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV56962019; called by muse, mutect2, varscan2
- PTH1R | c.531G>A p.E177= | Silent (SNP) | VAF 43/315 reads (14%) | catalogued as rs780016272; called by muse, mutect2, varscan2
- SGSH | c.126C>T p.N42= | Silent (SNP) | VAF 58/276 reads (21%) | catalogued as CM021148; called by muse, mutect2, varscan2
- SLC26A9 | c.711C>A p.I237= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV61601589; called by muse, mutect2
- SRXN1 | c.39C>A p.G13= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs1420946957; called by muse, mutect2, varscan2
- STAU2 | c.1188T>A p.G396= (on ENST00000524300 / NM_001164380.2; = p.G364= on NM_014393.2) | Silent (SNP) | VAF 18/167 reads (11%) | called by muse, mutect2, varscan2
- TUBB8B | c.1287G>A p.T429= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as rs1454328093; called by muse, mutect2
- ZIC4 | c.450C>T p.T150= | Silent (SNP) | VAF 56/392 reads (14%) | called by muse, mutect2, varscan2
- CCNYL2 | n.624-2603G>T | Intron (SNP) | VAF 35/233 reads (15%) | called by muse, mutect2, varscan2
- CST9LP1 | n.17C>T | RNA (SNP) | VAF 8/32 reads (25%) | catalogued as rs930939498; called by muse, mutect2, varscan2
- CYS1 | chr2:10083915 C>T | 5'Flank (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- ERCC6 | c.1397+7279G>A | Intron (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- GALT | c.1059+10C>G | Intron (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- P3H1 | c.1915-51G>T | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- TALDO1 | c.461+9T>A | Intron (SNP) | VAF 30/264 reads (11%) | called by mutect2, varscan2
- TRIQK | chr8:92884889 del T | 3'Flank (DEL) | VAF 29/254 reads (11%) | called by mutect2, pindel, varscan2
- UBA6 | chr4:67701375 C>T | 5'Flank (SNP) | VAF 35/195 reads (18%) | called by muse, mutect2, varscan2
